Surgical pathology report (de-identified scan), TCGA case TCGA-QU-A6IL, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Harvard Beth Israel, specimen TCGA-QU-A6IL-01A (Primary Tumor).

[page 1 of 3]
Pathology Examination

Name Birthdate Age Sex Pathology #
Male

Report to:
Gross Description by:

SPECIMEN SUBMITTED: RT & LT OBTURATOR L.N'S & PROSTATE & SEMINAL Vessicles

Procedure date Tissue received Report Date Diagnosed by

Previous biopsies: PROSTATE BX'S
GI BX
GALLBLADDER
GI BX

(and more)

DIAGNOSIS:

I. Right obturator lymph nodes (A-B):

One lymph node, no malignancy identified.

II. Left obturator lymph nodes (C-E):

Three lymph nodes, no malignancy identified.

III. Prostate and seminal vesicles (F-Q):

Adenocarcinoma, see synoptic report.

C&F *ICD-O-3*
path *Adenocarcinoma, acinar 8140/3*
Adenocarcinoma NOS 8140/3
Site Prostate NOS 061.9
9/26/13

*****PROSTATIC CARCINOMA SYNOPSIS*****

1. Type of specimen: Prostate and seminal vesicles.

2. Procedure: Radical prostatectomy.

3. Tumor type: Adenocarcinoma.

4. Tumor histologic grade (Gleason's):

Primary pattern - 3

Secondary pattern - 4

Score - 7/10

5. Tumor amount (radical prostatectomies):

[page 2 of 3]
Right: # Positive slides - 2 Left: # Positive slides - 5
Total - 3 Total - 8

Dorsal apex: # Positive slides - 0
Total - 2

Ventral apex: # Positive slides - 0
Total - 2

6. Pathologic stage: Confined to prostate.

7. Vascular/lymphatic invasion: Absent.

8. Perineural extension: Present, within prostate.

9. Surgical margins:

Inked capsular resection margins: Negative.

Inked bladder margin: Negative.

Inked apex margin: Negative.

10. Seminal vesicles: Not involved by tumor.

11. Lymph nodes:

Right pelvic: Total number - 1 # Positive - 0

Left pelvic: Total number - 3 # Positive - 0

GROSS:

CLINICAL: Prostate carcinoma.

Specimen is received in three parts:

Part I: Received fresh labeled [REDACTED] the medical record number and "right obturator lymph nodes" is a 4.0 x 2.0 x 1.5 cm lobulated fatty tissue from which two red-brown rubbery fatty possible lymph nodes, 1.7 x 0.8 x 0.6 cm and 3.3 x 1.2 x 0.6 cm, are identified. Each lymph node is bisected and the tissue is submitted in its entirety in cassettes coded A-B.

Part II: Received fresh labeled [REDACTED] the medical record number and "left obturator lymph nodes" is a 4.0 x 2.8 x 1.5 cm yellow lobulated fatty tissue from which three pink-tan rubbery fatty possible lymph nodes ranging from 0.5 x 0.3 x 0.2 cm to 3.5 x 1.3 x 0.8 cm are dissected. Represented as follows:

C = two whole possible lymph nodes

D-E = largest lymph node, bisected

Part III: Received fresh labeled [REDACTED], the medical record number and "prostate and seminal vesicles" is a 45 gram symmetrical

[page 3 of 3]
prostate gland with up to 2.6 cm attached vas deferens with an average diameter of 0.4 cm and attached right and left seminal vesicles averaging 3.5 x 1.2 x 0.7 cm. The prostate measures 5.2 cm (open to base), 4.5 cm (side-to-side) and 3.8 cm (anterior to posterior). The seminal vesicles are pink-gray, convoluted and unremarkable. Upon sectioning, there is no identifiable involvement by tumor. The outer surface of the prostate gland has a red-brown shaggy intact capsule in which the right is inked in black and the left is inked in green. The urethral margin (apex) is shaved and sectioned in a clock-like fashion. The ureteral margin (base) is shaved and sectioned in a clock-like fashion. The remainder glandular tissue is serially sectioned from apex to base. The prostatic parenchyma is focally nodular predominantly in the posterior left and right lateral aspects. The fibromuscular band dividing the right and left halves of the prostate is compressed to the left. There are small firm indurated yellow areas in the right posterior aspect and there is a moderate amount of corpora amylasia centrally surrounding the prostatic urethra. Represented as follows:

F = right vas deferens and seminal vesicle
G = left vas deferens and seminal vesicle
H = anterior apical margin
I = posterior apical margin
J = anterior base margin
K = posterior base margin
L-N = right apex, mid and base respectively
O-Q = left apex, mid and base respectively
R-V = Additional Left

By his/her signature above, the senior physician certifies that he/she personally conducted a gross and/or microscopic examination of the described specimen(s) and rendered or confirmed the diagnosis(es) related thereto.

Immunohistochemistry test(s), if applicable, were developed and their performance characteristics were determined by

They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA - 88) as qualified to perform high complexity clinical laboratory testing.

Criteria	6/11/13	Yes	No
Diagnostic Discrepancy			
His/AA Discrepancy			

Source: NCI Genomic Data Commons file c1807a5c-e03b-4ce2-85e2-261ba8d21379 (TCGA-QU-A6IL.EF13AC98-FA7C-442C-A6A4-A5E7ECB2596D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).